Somatic mutation profile of tumor specimen TCGA-B0-5120-01A (aliquot TCGA-B0-5120-01A-01D-1421-08) from TCGA case TCGA-B0-5120, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.7 years (26,559 days).
Specimen TCGA-B0-5120-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe512699-d2e2-472d-beb0-f56ee3f0d195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5120-11A (Solid Tissue Normal), aliquot TCGA-B0-5120-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55aa2ecd-500b-4d72-bcc7-2c46cc670634

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 2, 5'Flank 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV52508617; called by muse, mutect2, varscan2
- AMHR2 | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs758179091, COSV57685626; called by muse, mutect2, varscan2
- CD22 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV50051981; called by muse, mutect2, varscan2
- CD300E | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60790420; called by muse, mutect2
- CMTM1 | c.403A>G p.R135G (on ENST00000457188 / NM_181269.3; = p.R252G on NM_052999.4) | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51748578; called by muse, mutect2, varscan2
- DCAF13 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV52571575; called by muse, mutect2, varscan2
- DDR1 | c.2599C>T p.Q867* (on ENST00000324771; = p.Q830* on NM_001954.4) | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV61320932; called by muse, mutect2, varscan2
- DGKH | c.387C>T p.I129= | Splice Region (SNP) | VAF 13/239 reads (5%) | catalogued as COSV54931375; called by muse, mutect2
- DNMT3A | c.1753A>C p.M585L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as COSV53049961, COSV53063642; called by muse, mutect2, varscan2
- DRD2 | c.285+1G>A p.X95_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60757340; called by muse, mutect2, varscan2
- EMILIN1 | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53154411; called by muse, mutect2, varscan2
- GALNT7 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53929232; called by muse, mutect2
- LAMB4 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs555539125, COSV52718028; called by muse, mutect2, varscan2
- LAMC1 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV51139372; called by muse, mutect2, varscan2
- LOXL4 | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.155); catalogued as COSV53256421; called by muse, mutect2, varscan2
- LRCH2 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV57749613; called by muse, mutect2
- M6PR | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV50002865; called by muse, mutect2, varscan2
- MIA3 | c.4285A>T p.N1429Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV60512276; called by muse, mutect2, varscan2
- MIEF1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs777054252, COSV57478737; called by muse, mutect2, varscan2
- MRC1 | c.2619-1G>A p.X873_splice | Splice Site (SNP) | VAF 103/456 reads (23%) | catalogued as COSV99519336; called by muse, mutect2, varscan2
- MS4A14 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV100279637, COSV55728894, COSV55729651; called by muse, mutect2, varscan2
- NUP133 | c.2077-1G>T p.X693_splice | Splice Site (SNP) | VAF 11/73 reads (15%) | catalogued as COSV54570599; called by mutect2, varscan2
- PCDH15 | c.4604C>A p.P1535Q | Missense Mutation (SNP) | VAF 19/393 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.995); catalogued as rs1374646895, COSV64690403; called by muse, mutect2
- PFKM | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56657046; called by muse, mutect2, varscan2
- PPHLN1 | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV56730501; called by muse, mutect2, varscan2
- RP1 | c.2889A>T p.K963N | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV55115584; called by muse, mutect2, varscan2
- SERPINF2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60664265; called by muse, mutect2, varscan2
- SFRP4 | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV101460873, COSV71412367; called by muse, mutect2, varscan2
- SLC18A1 | c.107T>A p.M36K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV52347839; called by muse, mutect2, varscan2
- SLC2A14 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs763180661, COSV61586407, COSV61586472; called by muse, mutect2, varscan2
- SNRNP200 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs144219123; called by muse, mutect2, varscan2
- SNX27 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64326151; called by muse, mutect2, varscan2
- SNX29 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73754445; called by muse, mutect2, varscan2
- TEX11 | c.1042C>T p.H348Y (on ENST00000344304; = p.H333Y on NM_031276.3) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV60229892; called by muse, mutect2, varscan2
- TTN | c.45632C>T p.P15211L (on ENST00000591111; = p.P7787L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | PolyPhen benign (0.328); catalogued as COSV60016697; called by muse, mutect2, varscan2
- TXN | c.5T>A p.V2E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100996227; called by mutect2, varscan2
- UFL1 | c.1686A>G p.A562= | Splice Region (SNP) | VAF 48/177 reads (27%) | catalogued as COSV65149795; called by muse, mutect2, varscan2
- UTP14A | c.2185A>C p.I729L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64086798; called by muse, mutect2
- WDR35 | c.2053G>A p.D685N (on ENST00000345530 / NM_001006657.2; = p.D674N on NM_020779.4) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as COSV55602356; called by muse, mutect2, varscan2
- ZCCHC17 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs930150111, COSV60002039; called by muse, mutect2, varscan2
- ZNF708 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV63607332; called by muse, mutect2, varscan2
- ABCA10 | c.2068del p.S690Qfs*2 | Frame Shift Del (DEL) | VAF 33/145 reads (23%) | called by mutect2, pindel, varscan2
- MFSD2B | c.169del p.A57Pfs*16 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- PBRM1 | c.399dup p.Y134Ifs*2 | Frame Shift Ins (INS) | VAF 34/119 reads (29%) | called by mutect2, pindel, varscan2
- POLR2A | c.2041del p.L681Sfs*33 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- SNRPD2 | c.182+1del p.X61_splice | Splice Site (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- ALG12 | c.591G>A p.L197= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV58206909; called by muse, mutect2, varscan2
- CACNA1S | c.1509G>T p.V503= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV62938982; called by muse, mutect2, varscan2
- CCDC157 | c.459C>A p.P153= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV57838843; called by muse, mutect2, varscan2
- CNOT1 | c.114G>A p.R38= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV57769165; called by muse, mutect2
- COLEC12 | c.52C>A p.R18= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs754847272, COSV68370238; called by muse, mutect2, varscan2
- DISP1 | c.3963T>C p.A1321= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV52658172; called by muse, mutect2, varscan2
- MAP3K15 | c.2388G>A p.S796= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs1040624680, COSV58829070; called by muse, mutect2, varscan2
- NAV2 | c.6705G>A p.L2235= (on ENST00000396087 / NM_001244963.2; = p.L2176= on NM_145117.5) | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV60658849; called by muse, mutect2
- PDZD8 | c.1167G>T p.G389= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV57825154; called by muse, mutect2, varscan2
- PFKFB1 | c.621G>A p.L207= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs1306053522, COSV66628189; called by muse, mutect2, varscan2
- PLA2R1 | c.2940T>C p.S980= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV51777880; called by muse, mutect2, varscan2
- SLC22A10 | c.78C>G p.P26= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs773812260, COSV60421130; called by muse, mutect2, varscan2
- STXBP5 | c.2979C>T p.A993= (on ENST00000321680 / NM_001127715.2; = p.A957= on NM_139244.4) | Silent (SNP) | VAF 87/402 reads (22%) | catalogued as COSV51651465; called by muse, mutect2, varscan2
- SUV39H1 | c.135C>A p.V45= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV61920587, COSV61920776; called by muse, mutect2, varscan2
- TMC3 | c.1833T>C p.F611= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV63922919; called by muse, mutect2
- USHBP1 | c.1551C>T p.L517= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53103322, COSV53104560; called by muse, varscan2
- ZNF680 | c.1347T>C p.L449= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59015172; called by muse, mutect2, varscan2
- ZNF782 | c.1983C>T p.L661= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as COSV56652303; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848593 G>C | 5'Flank (SNP) | VAF 11/66 reads (17%) | catalogued as rs757326910; called by muse, mutect2, varscan2
- DOCK8 | chr9:214612 C>A | 5'Flank (SNP) | VAF 12/34 reads (35%) | catalogued as COSV66688183; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1138A>G | RNA (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
